Surgical pathology report (de-identified scan), TCGA case TCGA-08-0355, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0355-01A (Primary Tumor).

[page 1 of 2]
TCGA-08-0355

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, right temporal lobe, biopsy: Glioblastoma multiforme (Astrocytoma, WHO grade IV).
- B. Brain, right temporal lobe, excision: Glioblastoma multiforme (Astrocytoma, WHO grade IV).
- C. Brain, right temporal lobe, CUSA contents: Glioblastoma multiforme (Astrocytoma, WHO grade IV).

Intraoperative Diagnosis

FS1 (A) Brain, right temporal lobe tumor, biopsy: High-grade infiltrating glioma, consistent with high-grade astrocytoma. [REDACTED]

Gross Description

The specimen is received fresh in three parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "1 - right temporal lobe tumor," and consists of four unoriented fragments of yellow-pink, soft tissue measuring 0.8 x 0.4 x 0.2 cm in aggregate. The fragments are bisected, and one-half of each is submitted as FS1, the remnant of which is submitted in cassette A1. The entire remainder of the specimen is then submitted in cassette A2.

Part B is additionally labeled "right temporal tumor," and consists of five unoriented, tan-pink and gray-white, soft tissue fragments measuring 4.3 x 2.5 x 2.2 cm in aggregate. The entire specimen is submitted in cassettes B1-B4.

Part C is additionally labeled "right temporal tumor, CUSA specimen," and consists of multiple unoriented, red-tan fragments of soft tissue measuring 4.2 x 3.7 x 1.7 cm in aggregate. The entire specimen is submitted in cassettes C1-C4.

[page 2 of 2]
Clinical History

This is a with a right temporal lobe tumor.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Source: NCI Genomic Data Commons file 502fc38a-43f4-4b0c-999a-ba34a293a00e (TCGA-08-0355.FFB7868B-4900-4C98-9E9A-690916797028.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).